Somatic mutation profile of tumor specimen 0DBM2J from CCDI case PBBLDX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.9 years (3,999 days).
Specimen 0DBM2J: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de6f2f93-a081-40f9-b144-0bc9823d6f95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBM2K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84a655b9-e66a-4aa4-8374-47a78ee214e5

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Del 1, 5'UTR 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 132/1067 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- OR2G2 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 68/704 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs372540193, COSV100189977; called by muse, mutect2
- PLXND1 | c.3539C>T p.T1180M | Missense Mutation (SNP) | VAF 55/576 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs528635984, COSV60714362; called by muse, mutect2, varscan2
- USF3 | c.6308del p.P2103Rfs*41 | Frame Shift Del (DEL) | VAF 76/665 reads (11%) | catalogued as COSV57070990; called by mutect2, varscan2
- ZBED5 | c.1832T>G p.L611R | Missense Mutation (SNP) | VAF 32/712 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.063); catalogued as rs780011941; called by muse, mutect2
- CKAP5 | c.1532A>C p.K511T | Missense Mutation (SNP) | VAF 116/816 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FMR1 | c.308A>C p.Y103S | Missense Mutation (SNP) | VAF 101/960 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- NR2C1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 110/1102 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- TTC6 | c.1357T>C p.Y453H (on ENST00000267368; = p.Y1819H on NM_001310135.3) | Missense Mutation (SNP) | VAF 76/657 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 26/850 reads (3%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 28/227 reads (12%) | called by muse, varscan2
- ST6GALNAC1 | c.1605+55C>T | Intron (SNP) | VAF 19/225 reads (8%) | catalogued as rs1368410905; called by muse, mutect2
